Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A1DA, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A1DA-01A (Primary Tumor).

(First Tumor)

Tumor Site:	Cecum Proximal
Date of Cancer Sample Procurement:	
Histology:	Adenocarcinoma
Description of other histology:	
Grade:	Moderately Differentiated
Mucinous:	☒ No ☐ Yes ☐ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No ☐ Yes ☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☒ No ☐ Yes ☐ Unknown
Host Response:	Lymphoid Aggregates
Crohn's like reaction	☐ None ☒ Yes ☐ Unknown
Plasma cell rich stroma	☐ No ☐ Yes ☐ Unknown
Growth Pattern:	☐ Expansile ☒ Invasive ☐ Expansile and Invasive ☐ Unknown
Inflammatory Bowel Disease	☐ No ☐ Yes ☒ Unknown
Angiolymphatic Invasion:	☐ No ☒ Yes ☐ Unknown
Mutator Phenotype:	☒ No ☐ Yes ☐ Unknown
Number of Slides	1
Garland Necrosis present:	☐ No ☐ Yes ☒ Yes (Focal) ☐ Unknown
TIL Cells / HPF	2.6
Pathologist Comment:	no nl mucosa mostly ade

Source: NCI Genomic Data Commons file 8ef76b35-e00a-4313-8aa5-24e2bb4e5d12 (TCGA-DM-A1DA.8DECB6DA-5F5F-4475-A601-5252BC4BD486.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).